Gene-level copy-number profile of tumor specimen BLGSP-71-30-00660-01A from CGCI case BLGSP-71-30-00660, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 66.5 years (24,272 days).
Specimen BLGSP-71-30-00660-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Cervical; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c38c7545-7c87-4b01-8228-11a44c498886.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-30-00660-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/b0f17607-2a46-49b3-839c-63de235b1b87

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 130; copy number 1: 4,460; copy number 2: 52,143; copy number 3: 2,051; copy number 4: 95; copy number 5: 1; copy number 7: 2; copy number 13: 1; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 130 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,894,116–74,897,835, 2 genes: PMS2P5, Y_RNA.
- chr14:105,672,308–106,481,706, 126 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:75,391,955–75,416,787, 3 genes, copy number 7–13 (within-gene range 3–13): AC211486.1, TRIM73, NSUN5P1.
- chr10:44,712–46,884, 1 gene, copy number 15: AL713922.1.
- chr10:68,717,311–68,717,795, 1 gene, copy number 5: AL513534.3.

Autosomal genes at a single copy (total copy number 1): 1,608. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
